Somatic mutation profile of tumor specimen TCGA-BI-A0VS-01A (aliquot TCGA-BI-A0VS-01A-11D-A10S-08) from TCGA case TCGA-BI-A0VS, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 48.8 years (17,839 days).
Specimen TCGA-BI-A0VS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35757f6a-f964-4769-95e7-ad5a2a7e6ddb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BI-A0VS-10A (Blood Derived Normal), aliquot TCGA-BI-A0VS-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66f0368d-cb12-4b44-9b8b-5fd4f7bbaf6b

The open-access MAF lists 125 somatic variants for this specimen: 93 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 31, Nonsense Mutation 9, Splice Site 2, In Frame Del 2, Frame Shift Ins 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM131 | c.3955G>C p.E1319Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); catalogued as COSV51770253, COSV51770622, COSV51771645; called by muse, mutect2, varscan2
- A1BG | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs533605370, COSV54050119; called by muse, mutect2, varscan2
- ABR | c.1742A>C p.K581T (on ENST00000302538 / NM_021962.5; = p.K544T on NM_001092.5) | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV52142655; called by muse, mutect2, varscan2
- ACP6 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100984163; called by muse, mutect2
- ACP6 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65076383; called by muse, mutect2, varscan2
- ADAM29 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV63661412; called by muse, mutect2, varscan2
- ADAMTSL4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 182/292 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV54997519; called by muse, mutect2, varscan2
- ASPM | c.9698G>A p.R3233Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1023109833, COSV54126257; called by muse, mutect2, varscan2
- ATG7 | c.679-1G>A p.X227_splice | Splice Site (SNP) | VAF 90/194 reads (46%) | catalogued as COSV61611530; called by muse, mutect2, varscan2
- CCDC114 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs372889077, COSV59555734; called by muse, mutect2, varscan2
- CCDC73 | c.1441C>G p.Q481E | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV58796325, COSV58806787; called by muse, mutect2, varscan2
- CDC42EP4 | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1466277678, COSV59962168; called by muse, varscan2
- CDH12 | c.438C>G p.F146L | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66388805, COSV66392944; called by muse, mutect2, varscan2
- CDK10 | c.226_228del p.K76del (on ENST00000353379 / NM_052988.5; = p.K5del on NM_052987.4) | In Frame Del (DEL) | VAF 18/131 reads (14%) | catalogued as rs1265716105; called by mutect2, pindel, varscan2
- CELSR2 | c.3668G>A p.R1223H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV54768278; called by muse, mutect2
- CFAP69 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV60184619; called by muse, mutect2, varscan2
- CKMT2 | c.920G>A p.W307* | Nonsense Mutation (SNP) | VAF 31/194 reads (16%) | catalogued as rs746721046, COSV54172402; called by muse, mutect2, varscan2
- COQ3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as COSV54639238; called by muse, mutect2, varscan2
- CPSF7 | c.1399C>T p.R467W (on ENST00000394888 / NM_001136040.4; = p.R510W on NM_024811.4) | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV61210440; called by muse, mutect2, varscan2
- CPXCR1 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.162); catalogued as COSV52161409; called by muse, mutect2, varscan2
- CWF19L1 | c.1327C>A p.Q443K | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV62499037; called by muse, mutect2, varscan2
- CWH43 | c.1703T>G p.L568R | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56936858, COSV56941199; called by muse, mutect2, varscan2
- DDX42 | c.1332G>C p.K444N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63789570; called by muse, mutect2, varscan2
- DNAJC5 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946559411, COSV62670880; called by muse, mutect2, varscan2
- EIF2B4 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs770388291, COSV52006798; called by muse, mutect2, varscan2
- EIF3D | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.044); catalogued as COSV53402969; called by muse, varscan2
- ELK3 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV57385882, COSV99957596; called by muse, mutect2, varscan2
- EPAS1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs759634197, CM148529, COSV55384867; called by muse, mutect2, varscan2
- ERP27 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs760186558, COSV56762584; called by muse, mutect2, varscan2
- FAM71B | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV57227977, COSV57228705; called by muse, mutect2, varscan2
- FBN1 | c.6011A>G p.Y2004C | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57311556; called by muse, mutect2, varscan2
- FBN1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 168/498 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV57311564; called by muse, mutect2, varscan2
- FREM1 | c.5555G>C p.G1852A | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV66519339; called by muse, mutect2, varscan2
- GLRA2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 91/492 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV54335383, COSV54338436; called by muse, varscan2
- GPR158 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as COSV66266692; called by muse, mutect2, varscan2
- GRHL2 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.439); catalogued as COSV99306066; called by muse, mutect2
- GRN | c.1404G>C p.Q468H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV50006411; called by muse, mutect2
- HROB | c.53A>C p.E18A | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55369002; called by muse, mutect2, varscan2
- HSPB8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs757293016, COSV56136872, COSV56137127, COSV56137340; called by muse, mutect2, varscan2
- INTU | c.1735A>G p.T579A | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs755278340, COSV58870035; called by muse, mutect2, varscan2
- KCNC4 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs140378578, COSV100873629; called by muse, mutect2, varscan2
- KMT2C | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV51402639, COSV51501644; called by muse, mutect2, varscan2
- KPNA2 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57856996; called by muse, mutect2, varscan2
- KRT35 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs371011501; called by muse, mutect2, varscan2
- LAIR1 | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57306312; called by muse, mutect2, varscan2
- LENG9 | c.419C>G p.S140W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56617702, COSV56619615; called by muse, mutect2, varscan2
- LLPH | c.346A>C p.S116R | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.04); catalogued as COSV56981431, COSV56982095; called by muse, mutect2, varscan2
- LPIN3 | c.2411C>T p.T804M | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201841413; called by muse, mutect2, varscan2
- LRIT3 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as rs777757196, COSV59983151; called by muse, mutect2, varscan2
- MAP3K15 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58827029; called by muse, mutect2, varscan2
- MAP7D3 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 140/245 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV60170293; called by muse, mutect2, varscan2
- MFSD6 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV55621543; called by muse, mutect2, varscan2
- MST1R | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV56565814; called by muse, mutect2, varscan2
- NLRP5 | c.1229G>C p.R410T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.838); catalogued as COSV66762791, COSV66767825; called by muse, mutect2, varscan2
- NRIP1 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs543344464, COSV59655991; called by muse, mutect2, varscan2
- OR6K3 | c.548C>T p.P183L (on ENST00000368146; = p.P167L on NM_001005327.2) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63745394; called by muse, mutect2, varscan2
- OR8U1 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV56414469; called by muse, mutect2, varscan2
- PAK3 | c.586G>C p.E196Q (on ENST00000262836 / NM_001324328.2; = p.E181Q on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.266); catalogued as COSV53271584; called by muse, mutect2, varscan2
- PAPPA2 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62774649, COSV62781716; called by muse, mutect2, varscan2
- PCDH15 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57273159; called by muse, mutect2, varscan2
- PCDHGB2 | c.1473C>G p.I491M | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53912750; called by muse, mutect2, varscan2
- PCDHGB2 | c.1738C>G p.R580G | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53912756; called by muse, varscan2
- PCDHGB2 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV53907943; called by muse, varscan2
- PCDHGB2 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 63/164 reads (38%) | catalogued as COSV53912773; called by muse, varscan2
- PDGFC | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 44/114 reads (39%) | catalogued as COSV56846398; called by muse, mutect2, varscan2
- PHF3 | c.4792C>T p.Q1598* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as COSV50314462; called by muse, mutect2, varscan2
- PHKA1 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV59803060; called by muse, mutect2, varscan2
- PIK3C2B | c.3637G>C p.D1213H | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV65809821; called by muse, mutect2, varscan2
- PIK3C3 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs376188539; called by muse, mutect2, varscan2
- PMM2 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.84); catalogued as COSV51630980; called by muse, mutect2, varscan2
- PNPLA6 | c.2605C>T p.R869* (on ENST00000414982 / NM_001166111.2; = p.R821* on NM_006702.5) | Nonsense Mutation (SNP) | VAF 48/139 reads (35%) | catalogued as rs781417400, COSV55374900; called by muse, mutect2, varscan2
- PSMA8 | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100378597, COSV57601430; called by muse, mutect2
- RBM6 | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV56480467; called by muse, mutect2
- REPIN1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759469837, COSV68291980; called by muse, mutect2, varscan2
- RTL4 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV61205763; called by muse, mutect2
- SCCPDH | c.991-1G>A p.X331_splice | Splice Site (SNP) | VAF 36/100 reads (36%) | catalogued as COSV63618179; called by muse, mutect2, varscan2
- SLC16A5 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 138/456 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.286); catalogued as COSV61675550, COSV61675960; called by muse, varscan2
- SLC16A5 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 378/1117 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV61675560; called by muse, varscan2
- SLC9A1 | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs556347900, COSV56051913; called by muse, mutect2, varscan2
- SPRY3 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 22/389 reads (6%) | catalogued as COSV57142115; called by muse, mutect2
- SRSF1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.893); catalogued as COSV51964296, COSV51965809; called by muse, mutect2, varscan2
- SSBP2 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV57793387; called by muse, mutect2, varscan2
- SUMO1 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66260089; called by muse, mutect2, varscan2
- TET3 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69641171; called by muse, mutect2
- TEX2 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV51978368; called by muse, mutect2, varscan2
- TSGA10 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1167858807, COSV61822382; called by muse, mutect2, varscan2
- ZNF148 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV62302748; called by muse, mutect2, varscan2
- ZNF462 | c.4121G>T p.C1374F | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52932513; called by muse, mutect2, varscan2
- ZNF573 | c.1579G>A p.E527K (on ENST00000536220 / NM_001172692.1; = p.E469K on NM_152360.3) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.671); catalogued as rs1255730020, COSV59823885; called by muse, mutect2, varscan2
- ZNF638 | c.4772G>A p.G1591D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs1320601466, COSV52483375; called by muse, mutect2
- IFNGR2 | c.608_609dup p.P204Nfs*27 | Frame Shift Ins (INS) | VAF 48/122 reads (39%) | called by mutect2, pindel, varscan2
- RNF149 | c.845_847del p.I282del | In Frame Del (DEL) | VAF 9/69 reads (13%) | called by pindel, varscan2
- WDR44 | c.1889_1892del p.V630Dfs*17 | Frame Shift Del (DEL) | VAF 32/148 reads (22%) | called by mutect2, pindel, varscan2
- ACP6 | c.930C>T p.S310= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV65076390; called by muse, mutect2
- ACVR1C | c.387G>C p.A129= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV54644462, COSV54646162, COSV99694672; called by muse, mutect2, varscan2
- CADM1 | c.1248C>T p.D416= | Silent (SNP) | VAF 60/133 reads (45%) | catalogued as rs750612978, COSV59005190; called by muse, mutect2, varscan2
- CDC42EP4 | c.432G>A p.V144= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV59962159; called by muse, varscan2
- CNTN1 | c.1641C>T p.I547= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs747310388, COSV61635610, COSV61637169; called by muse, mutect2, varscan2
- FBN3 | c.5370G>A p.K1790= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as COSV54455453; called by muse, mutect2
- GLIS2 | c.544C>T p.L182= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV52109667; called by muse, mutect2, varscan2
- HERC6 | c.1101T>C p.S367= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV52028309; called by muse, mutect2, varscan2
- HLTF | c.795A>G p.E265= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV59499416; called by muse, mutect2
- HTR3A | c.72G>A p.R24= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs758434064, COSV55468352; called by muse, mutect2, varscan2
- IL9R | c.1212G>A p.T404= | Silent (SNP) | VAF 65/111 reads (59%) | catalogued as rs756014316, COSV54898562; called by muse, mutect2, varscan2
- MYF5 | c.672C>T p.L224= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as rs1407548361, COSV57354626, COSV57356699; called by muse, mutect2, varscan2
- MYH15 | c.1260C>T p.N420= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs774875091, COSV56305700; called by muse, mutect2, varscan2
- NEB | c.10083C>T p.I3361= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as COSV50845002; called by muse, mutect2
- NSUN7 | c.81G>C p.L27= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1393658774, COSV57272907; called by muse, mutect2, varscan2
- OR11A1 | c.252G>A p.L84= | Silent (SNP) | VAF 68/107 reads (64%) | catalogued as COSV65820761; called by muse, mutect2, varscan2
- PIDD1 | c.2223G>A p.Q741= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV57192488; called by muse, mutect2, varscan2
- PPP4R1 | c.1455A>G p.P485= (on ENST00000400556 / NM_001042388.3; = p.P468= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV53280857; called by muse, mutect2, varscan2
- PRRC2B | c.5964C>T p.F1988= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs368857240; called by muse, mutect2, varscan2
- RHBDD3 | c.162G>A p.L54= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV53322928; called by muse, mutect2
- ROBO1 | c.1284C>T p.C428= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs1298413168, COSV71392430; called by muse, mutect2, varscan2
- RP1L1 | c.498G>A p.Q166= | Silent (SNP) | VAF 46/236 reads (19%) | catalogued as COSV61444119; called by muse, mutect2, varscan2
- TADA2A | c.918C>G p.L306= | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- TENT4A | c.1047G>T p.V349= | Silent (SNP) | VAF 17/171 reads (10%) | catalogued as COSV50094680; called by muse, mutect2
- TMEM190 | c.198C>T p.V66= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV52581460, COSV52581590; called by muse, mutect2
- TMTC4 | c.2133C>T p.I711= (on ENST00000376234 / NM_001350577.2; = p.I730= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 87/142 reads (61%) | catalogued as COSV60891271, COSV60891621, COSV60892452; called by muse, mutect2, varscan2
- TUBB8 | c.456C>T p.L152= | Silent (SNP) | VAF 18/217 reads (8%) | catalogued as rs782165651, COSV59114972; called by muse, mutect2
- TYR | c.270G>A p.Q90= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV54471787; called by muse, mutect2, varscan2
- VPS13B | c.1830C>T p.S610= | Silent (SNP) | VAF 50/304 reads (16%) | catalogued as COSV62017061; called by muse, mutect2, varscan2
- WDR19 | c.2607C>T p.Y869= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs371645967; called by muse, mutect2, varscan2
- ZNF770 | c.1257G>A p.L419= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as COSV62543939, COSV62544212; called by muse, mutect2, varscan2
- IL9R | c.29-1486G>A | Intron (SNP) | VAF 385/686 reads (56%) | catalogued as COSV54898553; called by muse, varscan2
